Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A8NN, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A8NN-01A (Primary Tumor).

[page 1 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 1
SEX: M
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

PROCEDURE:

VERIFIED BY:

year-old with long history of right chest pain and dysphagia. Esophageal cancer. Operative Procedure: Transhiatal esophagectomy.

PROCEDURE:

VERIFIED BY:

1. "Esophagus and proximal stomach" An 11 cm long specimen or section of esophagus and stomach; located 1.8 cm from proximal margin and abutting and/or obliterating gastroesophageal junction is a circumferential 4.5 cm wide x 10.5 circumference and 0.8 cm fungating ulcerated mass which abuts serosal/external surface. Just distal to this mass in the stomach is a 3.6 x 2.0 ulcer with raised, rolled borders, overlying a 5.5 x 5.0 x 5.0 cm cystic mass filled with necrotic material, surrounded by tan-white parenchyma that is contiguous with the fungating mass in the esophagus. This mass comes to within 1.0 cm of the distal staple lines. Mass abuts free surface of specimen in both the esophagus and stomach. Sampled.

1A-H. One full longitudinal section from proximal to distal.

1I-J. Additional samples of mass in relation to distal margin and external gastric surface.

1K-M. Paraesophageal lymph nodes (K=2 nodes, L-M=samples of one node each)

1N-O. Paragastric lymph nodes. (N=4 nodes, O=samples of one node)

2. "Cervical esophageal margin" A 0.5 cm long segment of esophagus, up to 1.0 cm in diameter open at one end and stapled at the other. Open end sampled.

PROCEDURE:

VERIFIED BY:

ESOPHAGEAL, CARDIAC AND GASTROESOPHAGEAL JUNCTION CARCINOMA:

Type of carcinoma: Adenocarcinoma. Arising at GE junction, not otherwise specified.

Depth of invasion: Adventitia.

Number of positive lymph nodes: 4/10

Extranodal metastasis: Unknown.

Pattern of invasion: Infiltrative and expansile.

Esophageal and gastric resection margins involved: No.

ICD O-3

Adenocarcinoma NOS 8140/3
Site ^{GE} Esophagus, distal third
path Gastroesophageal junction C15.5
C16.0

2011/17/14

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 2
SEX: M
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

Deep resection margin involved: No, however tumor very closely approaches inked resection margin.

TNM classification: T3 N1 Mx

PROCEDURE:

VERIFIED BY:

1. Esophagus and proximal stomach, transhiatal esophagogastrectomy: Invasive adenocarcinoma arising at GE junction not otherwise specified, invading to adventitia. Surgical resection margins negative. Four lymph nodes positive for metastatic adenocarcinoma, with external extension. See template for details.

2. Cervical esophageal margin: Negative for neoplasm.

I, the signing staff pathologist, have personally examined and interpreted the slides from this case.

Code:

Criteria	11/19/13	Yes	No

Source: NCI Genomic Data Commons file f3ddb2fd-5707-44c2-96dc-a3911684e0d6 (TCGA-L5-A8NN.D685E2F8-B3D3-4072-AF02-D57FCAD2F34B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).